Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6307, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6307-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

- A. RIGHT OVARIAN CYST
- B. LEFT OVARIAN CYST
- C. LEFT COLON, SIGMOID, UPPER RECTUM
- D. DISTAL DONUT
- E. PROXIMAL DONUT
- F. SMALL BOWEL NODULE

DIAGNOSIS:

- A. SOFT TISSUE, RIGHT OVARY, EXCISION:
- SEROUS CYSTADENOMA.
- B. SOFT TISSUE, LEFT OVARY, EXCISION:
- SEROUS CYSTADENOMA.
- C. RECTOSIGMOID COLON, SEGMENTAL RESECTION:
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH ULCERATION.
- TUMOR SIZE 5 CM.
- TUMOR INFILTRATES INTO THE SUBSEROA.
- MARGINS ARE NEGATIVE FOR CARCINOMA.
- TUBULAR ADENOMA.
- TWO OF SEVENTEEN LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/17).
- SEE TEMPLATE.
- D. COLON, DISTAL DONUT, EXCISION:
- COLONIC TYPE MUCOSA WITH NO PATHOLOGICAL ABNORMALITY.
- NEGATIVE FOR CARCINOMA.
- E. COLON, PROXIMAL DONUT, EXCISION:
- COLONIC TYPE MUCOSA WITH NO PATHOLOGICAL ABNORMALITY.
- NEGATIVE FOR CARCINOMA.
- F. SOFT TISSUE, SMALL BOWEL, EXCISION:
- ENDOSALPINGIOSIS, NEGATIVE FOR MALIGNANCY.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Rectal/rectosigmoid colon (Lower anterior resection)
Tumor Site:	Sigmoid Colon
Tumor Configuration:	Exophytic (polypoid)
Tumor Size:	5 x 4 x 3 cm.
Histologic Type:	Adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Extent of Invasion:	Subserosa
Margins:	Margins uninvolved by invasive carcinoma (Proximal, Distal, Radial)
Venous/Lymphatic Invasion:	Present
Perineural Invasion:	Absent
Additional Pathologic Findings:	Adenoma
Extent of Resection:	R0: Complete resection with grossly and microscopically negative margins
Lymph Nodes:	Positive (2/17) Extranodal extension
Implants:	Absent
Pathologic Stage:	pT3a N1 MX

SPECIMEN(S):

- A. RIGHT OVARIAN CYST B. LEFT OVARIAN CYST C. LEFT COLON, SIGMOID, UPPER RECTUM
- D. DISTAL DONUT E. PROXIMAL DONUT F. SMALL BOWEL NODULE

[page 2 of 3]
GROSS DESCRIPTION:

A. RIGHT OVARIAN CYST

Received fresh labeled with patient's name and "right ovarian cyst" is a 2.0 x 1.0 x 0.8 cm pink-tan cystic soft tissue fragment. A section is submitted for frozen section in FSA1 and the remainder of the specimen is submitted in cassette A2.

B. LEFT OVARIAN CYST

Received fresh labeled with patient's name and "left ovarian cyst" is a 1.5 x 0.4 x 0.3 cm pink-tan soft tissue fragment. The specimen is entirely submitted for frozen section in FSB1.

C. LEFT COLON, SIGMOID, UPPER RECTUM

Received fresh and labeled with patient's name and "left colon, sigmoid and upper rectum" is a segment of colon and rectum, measuring 20 cm in length and 6 cm in open circumference. The serosa is smooth. There is a pink-tan fungating mass 4 x 5 x 3 cm, located 4 cm from the rectal margin and 9.5 cm from the colonic margin. It appears to invade into the muscularis propria. There is a 0.7 x 0.4 x 0.3 cm. polyp located 0.5 cm from the mass towards the proximal colonic margin. Sixteen possible lymph nodes are found ranging in size from 0.4 to 1.7 cm in greatest dimension. Representative sections are submitted as follows:

C1: colonic margin

C2: rectal margin

C3-C5: mass and deep margin

C6: mass with polyp

C7: representative sections of normal appearing colonic mucosa

C8: five possible lymph nodes

C9: five possible lymph nodes

C10: four possible lymph nodes

C11-C13: one bisected lymph node each

D. DISTAL DONUT

Received in formalin and labeled with the patient name and "distal donut" is a ring of tan mucosa tissue measuring 0.9 cm in length with an outer circumference of 1.6 cm. It is bisected and there is a stapled surgical line present. The specimen is submitted in toto in cassette D1.

E. PROXIMAL DONUT

Received in formalin and labeled with the patient name and "proximal donut" is a ring of tan mucosa tissue with an outer circumference of 1.9 cm and measuring 0.8 cm in width. There are blue sutures present throughout the specimen. The specimen is submitted entirely in cassette E1.

F. SMALL BOWEL NODULE

Received fresh for frozen section evaluation labeled with the patient's name and "small bowel nodule excision" is a fragment of tan soft tissue measuring 2.0 x 0.5 x 0.4 cm. The tissue is bisected to show a firm white nodule measuring 1 x 0.5 x 0.5 cm. The entire specimen is submitted in a cassette FSF1.

ADDENDUM:

ANALYSIS OF MISMATCH REPAIR PROTEIN EXPRESSION

MLH1 Expression: Present

MSH2 Expression: Present

MSH6 Expression: Present

PMS2 Expression: Present

Expression of MLH1, MSH2, MSH6, and PMS2 in the tumor was evaluated by immunohistochemistry. Peritumoral lymphocytes and normal glands serve as internal positive controls expressing MLH1, MSH2, MSH6, and PMS2.

Testing for Microsatellite Instability has been ordered. The results will be issued in a separate report.

[page 3 of 3]
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 09806bc6-83d6-4fad-ba36-0541f72a8f28 (TCGA-G4-6307.FD16F984-2F04-487B-A553-90194C790FF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).